Somatic mutation profile of tumor specimen TCGA-H9-A6BY-01A (aliquot TCGA-H9-A6BY-01A-11D-A30E-08) from TCGA case TCGA-H9-A6BY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.8 years (23,297 days).
Specimen TCGA-H9-A6BY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1424a2fd-9ade-4ddf-8a44-b0cb2fd7ea9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H9-A6BY-10A (Blood Derived Normal), aliquot TCGA-H9-A6BY-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab95fcf0-9f9a-4d22-ad4c-97cf81d128d5

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Frame Shift Ins 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG2 | c.1913T>C p.V638A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV52945135; called by muse, mutect2, varscan2
- AKNA | c.3872C>T p.S1291F | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56336298; called by muse, mutect2, varscan2
- AQP2 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as rs747794240, COSV52229830; called by muse, mutect2, varscan2
- CD177 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs749352682; called by muse, mutect2, varscan2
- CD27 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV56949944; called by muse, mutect2, varscan2
- CHRNA10 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs369800306, COSV51709209; called by muse, mutect2, varscan2
- CRISPLD1 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51546593; called by muse, mutect2
- DPY19L4 | c.1732G>T p.A578S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.067); catalogued as COSV101363400, COSV68962661; called by muse, mutect2, varscan2
- FAT4 | c.5323G>A p.V1775I | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.983); catalogued as rs547537537, COSV58676874; called by muse, mutect2, varscan2
- HCN4 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1454748709, CM104901, COSV56082775; called by muse, mutect2, varscan2
- KMT2D | c.6354dup p.A2119Rfs*36 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs755159728; called by pindel, varscan2
- MLH3 | c.2021dup p.N674Kfs*13 | Frame Shift Ins (INS) | VAF 21/59 reads (36%) | catalogued as rs767782578; ClinVar: uncertain significance; called by mutect2, varscan2
- NDUFS3 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs9600, COSV55454236; called by muse, mutect2, varscan2
- PGAP4 | c.813G>T p.L271F | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs771493396, COSV66387496; called by muse, mutect2, varscan2
- PTPRA | c.2246T>A p.L749Q | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53780561; called by muse, mutect2, varscan2
- RP1L1 | c.6619C>A p.P2207T | Missense Mutation (SNP) | VAF 28/507 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.39); catalogued as COSV101222853, COSV66754081; called by muse, mutect2
- SBF1 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1569512384, COSV62366880; called by muse, mutect2, varscan2
- SLC10A2 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV55358188; called by muse, mutect2
- ZFYVE27 | c.220T>G p.L74V | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV61746549; called by muse, mutect2, varscan2
- ABCA12 | c.5012dup p.N1671Kfs*2 (on ENST00000272895 / NM_173076.3; = p.N1353Kfs*2 on NM_015657.3) | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- CERKL | c.294_295del p.F99Lfs*11 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by pindel, varscan2
- CCDC144A | c.63C>T p.Y21= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61403024; called by muse, mutect2, varscan2
- CDC20B | c.1536G>A p.T512= (on ENST00000381375 / NM_001170402.1; = p.T508= on NM_152623.2) | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs749147711, COSV57051424; called by muse, mutect2, varscan2
- GLI2 | c.3303C>T p.G1101= (on ENST00000361492 / NM_001374353.1; = p.G1118= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV58039517; called by muse, mutect2, varscan2
- KIF1A | c.501C>T p.R167= | Silent (SNP) | VAF 66/165 reads (40%) | catalogued as rs923432327, COSV57486723; called by muse, mutect2, varscan2
- SOGA3 | c.2259C>T p.A753= | Silent (SNP) | VAF 9/156 reads (6%) | catalogued as COSV64106198; called by muse, mutect2
- TMC7 | c.792G>A p.L264= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs766306886, COSV58582801; called by muse, mutect2, varscan2
